Surgical pathology report (de-identified scan), TCGA case TCGA-W5-AA2O, project TCGA-CHOL (Cholangiocarcinoma), tissue source site Mayo Clinic Rochester, specimen TCGA-W5-AA2O-01A (Primary Tumor).

Male
Surgery Date:

DIAGNOSIS:

Liver, right lobe and caudate lobe, resection: Grade 3 (of 4) adenocarcinoma consistent with intrahepatic cholangiocarcinoma forming a 9.0 x 6.5 x 5.8 cm mass. The noninvolved liver parenchyma shows mild steatosis, without abnormal fibrosis. The tumor is present at the inked surgical resection margin. Immunohistochemical stains (CK7, CK20, TTF-1, chromogranin, CDX2, synaptophysin) were performed on the paraffin embedded liver tissues. The neoplastic cells are reactive for CK7 and lack staining for CK20, TTF-1,

chromogranin, and synaptophysin. There is background staining with CDX2. The morphologic features and immunohistochemical findings support the above diagnosis.

Gallbladder, cholecystectomy: No diagnostic abnormalities.

Lymph node, pericholedochal, excision: A single pericholedochal lymph node is negative for tumor.

ICD-O-3

Cholangiocarcinoma 8160/3

Site: Intrahepatic bile duct c22.1

W 818114

Source: NCI Genomic Data Commons file 7eb09b65-a2b9-43da-9b39-0f3158ef70eb (TCGA-W5-AA2O.EDB0DC9B-6D0C-4591-81CA-BECD1BC27983.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).